Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EU, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EU-01A (Primary Tumor).

ICD O-3
Melanoma, epithelioid cell
8771/3
Site Uveal tract c69.4
QW 2/10/14

Enucleation of the left eye

Macroscopy

The eyeball measures 27X24 mm main lines with a segment of optic nerve of 5 mm.

At the section, a tumor nodule is observed at the postero-lateral part of the eyeball, measuring 16 mm main line. Tissue specimens are taken for cryopreservation prior fixation.

Microscopy

The tumor nodule observed macroscopically presents the microscopic appearance of an uveal melanoma. This tumor is composed exclusively of epithelioid cells. The cell atypias are severe. About 60% of the cells are pigmented with melanin. The mitotic activity is low (4 mitoses per 10 HPF). The tumor measures 16 main line and 10 mm in thickness at its median part.

There is an infiltration of the ciliary body and of the sclera, with tumor endovascular embolisms and extra-scleral extension forming a nodule of 3 mm. The optic nerve on its entire course and the meningeal sheaths are free of tumor.

Conclusion

Uveal melanoma composed of epithelioid cells.

Tumor size: 16 mm main line.

Infiltration of the ciliary body and of the sclera with a focal extra-scleral tumor nodule measuring 3 mm.

Mitotic activity: moderate..

Optic nerve on its entire course including the cut end and meningeal sheaths free of tumor.

Source: NCI Genomic Data Commons file d0b1eb09-7d55-4a6e-b9f7-2401b66cd6d9 (TCGA-V4-A9EU.74589A94-394C-40EC-BA77-D36B41E059ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).